CCDI case PBBSJU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/f6d3c61a-f326-4434-a63f-83182dd8006c

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 14.1 years (5,145 days).

Biospecimens (4 samples)
- Sample 0DFO16: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DFO1J, 0DFO1U (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFPV6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
